Somatic mutation profile of tumor specimen TCGA-OR-A5J9-01A (aliquot TCGA-OR-A5J9-01A-11D-A29I-10) from TCGA case TCGA-OR-A5J9, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 22.4 years (8,175 days).
Specimen TCGA-OR-A5J9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3c41dcaf-655f-4224-8bfc-ef35ef01352f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OR-A5J9-10A (Blood Derived Normal), aliquot TCGA-OR-A5J9-10A-01D-A29L-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/19ad7390-3f40-4dac-b3e5-263338639d2f

The open-access MAF lists 31 somatic variants for this specimen: 27 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 26, Silent 4, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CARD11 | c.3431G>A p.R1144H | Missense Mutation (SNP) | VAF 74/174 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as rs573740263, COSV67802537; called by muse, mutect2, varscan2
- CCDC54 | c.365C>T p.T122M | Missense Mutation (SNP) | VAF 47/110 reads (43%) | SIFT tolerated (0.31); PolyPhen benign (0.026); catalogued as rs781776011, COSV53759015; called by muse, mutect2, varscan2
- CFTR | c.249C>G p.F83L | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.042); catalogued as rs780975618, COSV50041440; called by muse, mutect2, varscan2
- ENC1 | c.397C>T p.R133W | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs773788171, COSV56629300; called by muse, mutect2, varscan2
- ENPP2 | c.1564G>C p.A522P (on ENST00000075322 / NM_001040092.3; = p.A574P on NM_006209.5) | Missense Mutation (SNP) | VAF 41/154 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99309319; called by muse, mutect2, varscan2
- FRMPD4 | c.3071C>A p.T1024N | Missense Mutation (SNP) | VAF 112/188 reads (60%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.417); catalogued as rs774466633; called by muse, mutect2, varscan2
- JAK2 | c.982A>G p.I328V | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as COSV67608581; called by muse, mutect2, varscan2
- NWD1 | c.629G>A p.R210Q | Missense Mutation (SNP) | VAF 65/228 reads (29%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.637); catalogued as rs867793000; called by muse, mutect2, varscan2
- PAPPA2 | c.146G>A p.R49H | Missense Mutation (SNP) | VAF 62/181 reads (34%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); catalogued as rs920503822, COSV62773244; called by muse, mutect2, varscan2
- PGK2 | c.1151A>C p.N384T | Missense Mutation (SNP) | VAF 64/137 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.316); catalogued as COSV59164510; called by muse, mutect2, varscan2
- RANBP3 | c.149A>T p.H50L | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.025); catalogued as COSV50386148; called by muse, mutect2, varscan2
- RBM44 | c.133G>A p.E45K (on ENST00000611254; = p.E679K on NM_001080504.2) | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as rs906001123; called by muse, mutect2, varscan2
- SCAF1 | c.3188C>G p.S1063C | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); catalogued as COSV62185043; called by muse, mutect2, varscan2
- STK4 | c.542G>A p.R181Q | Missense Mutation (SNP) | VAF 50/152 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs202070040, COSV65671898; called by muse, mutect2, varscan2
- VN1R2 | c.49A>G p.I17V | Missense Mutation (SNP) | VAF 24/104 reads (23%) | PolyPhen benign (0.031); catalogued as rs376857944; called by muse, varscan2
- ZBBX | c.602C>A p.P201H | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as rs770804757, COSV56786655; called by muse, mutect2, varscan2
- ABCA12 | c.687C>G p.F229L | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADGRA2 | c.353A>G p.N118S | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- APOB | c.13435del p.S4479Afs*9 | Frame Shift Del (DEL) | VAF 17/55 reads (31%) | called by mutect2, pindel, varscan2
- DNMT3B | c.223G>T p.D75Y | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- HYDIN | c.12226G>C p.V4076L | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- NUDT4 | c.367G>C p.E123Q | Missense Mutation (SNP) | VAF 60/212 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- PRDM9 | c.178G>A p.A60T | Missense Mutation (SNP) | VAF 62/225 reads (28%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- SPEF2 | c.1288G>A p.A430T | Missense Mutation (SNP) | VAF 70/315 reads (22%) | SIFT tolerated (0.63); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- UBA2 | c.461G>C p.G154A | Missense Mutation (SNP) | VAF 45/176 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- USP38 | c.2797A>G p.T933A | Missense Mutation (SNP) | VAF 46/217 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF585B | c.1276A>T p.I426F | Missense Mutation (SNP) | VAF 40/148 reads (27%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- AJAP1 | c.405G>A p.S135= | Silent (SNP) | VAF 10/19 reads (53%) | catalogued as rs1230640332, COSV65448938; called by muse, mutect2, varscan2
- C15orf48 | c.132A>G p.R44= | Silent (SNP) | VAF 15/47 reads (32%) | called by muse, varscan2
- HPN | c.603C>T p.A201= | Silent (SNP) | VAF 25/125 reads (20%) | catalogued as rs1014739669, COSV52883239; called by muse, mutect2, varscan2
- ZNF319 | c.249C>T p.H83= | Silent (SNP) | VAF 26/86 reads (30%) | catalogued as rs144999714; called by muse, mutect2, varscan2
